Gene-level copy-number profile of tumor specimen TCGA-92-8065-01A from TCGA case TCGA-92-8065, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.1 years (27,049 days).
Specimen TCGA-92-8065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.daf8186e-5d1d-450a-bbb6-5c87193fd631.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-92-8065-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f676cda7-128a-4521-adaf-15514233132c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 16,836; copy number 2: 34,518; copy number 3: 7,400; copy number 4: 318; copy number 6: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-92-8065-01A-11D-2243-01): tumor purity 0.5, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:191,029,576–191,174,835, 5 genes (within-gene range 0–1): STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27.
- chr3:29,526,251–29,934,156, 3 genes: RBMS3-AS2, MTND4LP9, RBMS3-AS1.
- chr4:86,594,315–87,141,054, 10 genes (within-gene range 0–1): PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1.
- chr4:169,917,761–169,975,904, 1 gene (within-gene range 0–1): LINC02275.
- chr4:169,945,981–170,372,311, 8 genes: AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512.
- chr22:25,742,144–26,031,045, 1 gene (within-gene range 0–1): MYO18B.
- chr22:25,876,854–25,903,247, 1 gene: MYO18B-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 710 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,840,514–82,808,021, 4 genes, copy number 6 (within-gene range 2–6): AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr3:158,105,855–158,545,730, 1 gene, copy number 6 (within-gene range 4–6): RSRC1.
- chr3:158,336,430–198,222,513, 705 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
